Somatic mutation profile of cancer-model specimen HCM-BROD-0121-C41-85B (2D Modified Conditionally Reprogrammed Cells, passage 8; aliquot HCM-BROD-0121-C41-85B-01D-A78L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0121-C41, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Ewing sarcoma; Tissue or organ of origin: Bone, NOS; Age at diagnosis: 14.2 years (5,196 days).
Specimen HCM-BROD-0121-C41-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5f5ec69-5dd5-4115-8e48-30562a01017a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0121-C41-10A (Blood Derived Normal), aliquot HCM-BROD-0121-C41-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6703bbe1-fba1-4da2-ad08-bbf538714f5b

The open-access MAF lists 75 somatic variants for this specimen: 55 protein-altering or splice-affecting, 10 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 10, Frame Shift Del 7, Intron 5, Frame Shift Ins 3, Splice Site 2, 3'UTR 2, Splice Region 2, In Frame Del 2, 5'UTR 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 391/392 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC053503.6 | c.737G>C p.R246P | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as rs565571477, COSV56675087; called by muse, mutect2, varscan2
- ADAMTS6 | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 108/108 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs140946308; called by muse, mutect2, varscan2
- FAM200B | c.1004C>G p.S335C | Missense Mutation (SNP) | VAF 98/132 reads (74%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as rs1485165996; called by muse, mutect2, varscan2
- GPR150 | c.5A>G p.E2G | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.026); catalogued as rs763040397; called by muse, mutect2, varscan2
- GPR156 | c.600G>C p.T200= | Splice Region (SNP) | VAF 14/82 reads (17%) | catalogued as COSV59939457; called by muse, mutect2, varscan2
- JAK1 | c.327G>C p.M109I | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); catalogued as COSV61089630, COSV99071476; called by muse, mutect2
- KDM2B | c.3118C>T p.R1040C | Missense Mutation (SNP) | VAF 88/90 reads (98%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs1555288565; called by muse, mutect2, varscan2
- LGI2 | c.65G>T p.C22F | Missense Mutation (SNP) | VAF 204/204 reads (100%) | SIFT tolerated (0.52); PolyPhen benign (0.025); catalogued as COSV66123615; called by muse, varscan2
- PCDH11X | c.3251G>A p.G1084D | Missense Mutation (SNP) | VAF 445/449 reads (99%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as COSV53490068; called by muse, mutect2, varscan2
- PCDHB9 | c.1837G>A p.G613R | Missense Mutation (SNP) | VAF 37/595 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.337); catalogued as rs782259092, COSV53383737; called by muse, mutect2
- RBM18 | c.329G>T p.R110I | Missense Mutation (SNP) | VAF 94/184 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as COSV101313789; called by muse, mutect2, varscan2
- RHBDF1 | c.598C>T p.H200Y | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.041); catalogued as rs1267410588; called by muse, mutect2, varscan2
- AKAP3 | c.704C>G p.P235R | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.079); called by muse, mutect2
- ARHGAP45 | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- ASTN2 | c.2663G>C p.S888T (on ENST00000313400 / NM_001365069.1; = p.S837T on NM_014010.5) | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BMX | c.1969C>A p.P657T | Missense Mutation (SNP) | VAF 107/146 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- C2orf16 | c.3626A>G p.K1209R | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.412); called by muse, mutect2
- CCDC40 | c.1917_1918del p.M640Dfs*33 | Frame Shift Del (DEL) | VAF 49/314 reads (16%) | called by pindel, varscan2
- CFHR4 | c.504T>A p.H168Q (on ENST00000367416 / NM_001201551.2; = p.H169Q on NM_001201550.3) | Missense Mutation (SNP) | VAF 15/267 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.686); called by muse, mutect2
- COX7A2L | c.109_110dup p.I38Sfs*9 | Frame Shift Ins (INS) | VAF 133/237 reads (56%) | called by mutect2, pindel, varscan2
- CRTC1 | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 19/221 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2
- DIDO1 | c.2953_2968dup p.H990Pfs*31 | Frame Shift Ins (INS) | VAF 78/174 reads (45%) | called by mutect2, varscan2
- E2F8 | c.632_636del p.K211Rfs*3 | Frame Shift Del (DEL) | VAF 112/157 reads (71%) | called by mutect2, pindel, varscan2
- FAT2 | c.6163T>A p.L2055M | Missense Mutation (SNP) | VAF 19/260 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.309); called by muse, mutect2
- HSPG2 | c.1822G>C p.D608H | Missense Mutation (SNP) | VAF 51/891 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- HTRA4 | c.468G>A p.G156= | Splice Region (SNP) | VAF 126/296 reads (43%) | called by muse, mutect2, varscan2
- ICE1 | c.4193_4204del p.I1398_V1401del | In Frame Del (DEL) | VAF 75/111 reads (68%) | called by mutect2, pindel, varscan2
- IGF2R | c.4729del p.A1577Pfs*5 | Frame Shift Del (DEL) | VAF 118/164 reads (72%) | called by mutect2, pindel, varscan2
- IL6ST | c.1925_1928del p.N642Sfs*4 | Frame Shift Del (DEL) | VAF 69/72 reads (96%) | called by mutect2, pindel, varscan2
- KCNJ12 | c.182A>G p.D61G | Missense Mutation (SNP) | VAF 83/700 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KDM5C | c.4612G>A p.A1538T | Missense Mutation (SNP) | VAF 31/31 reads (100%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KEAP1 | c.257_266dup p.A90Gfs*40 | Frame Shift Ins (INS) | VAF 98/143 reads (69%) | called by mutect2, varscan2
- KIF21A | c.73del p.I25Lfs*19 | Frame Shift Del (DEL) | VAF 138/451 reads (31%) | called by mutect2, pindel, varscan2
- LRRC47 | c.1504-1G>C p.X502_splice | Splice Site (SNP) | VAF 77/210 reads (37%) | called by muse, mutect2, varscan2
- MBTPS1 | c.434T>C p.V145A | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC6 | c.2523_2534del p.E841_T844del | In Frame Del (DEL) | VAF 8/49 reads (16%) | called by mutect2, pindel, varscan2
- NADK | c.259A>G p.I87V | Missense Mutation (SNP) | VAF 109/212 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUP133 | c.2177del p.I726Tfs*3 | Frame Shift Del (DEL) | VAF 30/235 reads (13%) | called by mutect2, pindel, varscan2
- OSBPL11 | c.1367C>T p.T456I | Missense Mutation (SNP) | VAF 17/302 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); called by muse, mutect2
- POLR1A | c.1441A>G p.R481G | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PPFIBP1 | c.2177-2A>C p.X726_splice (on ENST00000318304 / NM_177444.3; = p.X720_splice on NM_003622.4) | Splice Site (SNP) | VAF 14/251 reads (6%) | called by muse, mutect2
- PRAMEF27 | c.1280C>T p.T427I | Missense Mutation (SNP) | VAF 42/415 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRAMEF27 | c.1279A>C p.T427P | Missense Mutation (SNP) | VAF 40/413 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- RUSC2 | c.2507A>T p.E836V | Missense Mutation (SNP) | VAF 31/293 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TNPO3 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 125/251 reads (50%) | called by muse, mutect2, varscan2
- TSGA10 | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- TTC28 | c.7226A>G p.D2409G | Missense Mutation (SNP) | VAF 63/257 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- TTN | c.80471C>T p.A26824V (on ENST00000591111; = p.A19400V on NM_003319.4) | Missense Mutation (SNP) | VAF 15/106 reads (14%) | PolyPhen benign (0.265); called by muse, mutect2, varscan2
- TUT7 | c.253A>T p.S85C | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); called by muse, mutect2
- USP32 | c.2237A>G p.N746S | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- WDR97 | c.1493_1497del p.L498Pfs*161 | Frame Shift Del (DEL) | VAF 180/482 reads (37%) | called by mutect2, pindel, varscan2
- ZC3H12C | c.2149G>T p.A717S | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZDHHC1 | c.1187C>A p.A396E | Missense Mutation (SNP) | VAF 129/129 reads (100%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFHX4 | c.335A>G p.N112S | Missense Mutation (SNP) | VAF 15/417 reads (4%) | SIFT tolerated (0.88); PolyPhen benign (0.04); called by muse, mutect2
- CABIN1 | c.4077C>T p.Y1359= | Silent (SNP) | VAF 138/421 reads (33%) | catalogued as rs770122806, COSV104371027; called by muse, mutect2, varscan2
- CADPS2 | c.1992T>C p.S664= | Silent (SNP) | VAF 10/180 reads (6%) | called by muse, mutect2
- FGR | c.105G>T p.G35= | Silent (SNP) | VAF 45/414 reads (11%) | catalogued as COSV64969819; called by muse, mutect2, varscan2
- HNRNPU | c.1191C>T p.N397= (on ENST00000283179; = p.N459= on NM_004501.3) | Silent (SNP) | VAF 29/245 reads (12%) | catalogued as rs778730784, COSV51691650; ClinVar: likely benign; called by muse, mutect2, varscan2
- MBTPS2 | c.927T>C p.C309= | Silent (SNP) | VAF 45/256 reads (18%) | called by muse, mutect2, varscan2
- NR4A2 | c.1741T>C p.L581= | Silent (SNP) | VAF 29/236 reads (12%) | catalogued as rs1277022330; called by muse, mutect2, varscan2
- POTEF | c.2391T>A p.A797= | Silent (SNP) | VAF 113/559 reads (20%) | called by muse, mutect2, varscan2
- RFXAP | c.277T>C p.L93= | Silent (SNP) | VAF 6/26 reads (23%) | called by mutect2, varscan2
- TICRR | c.1113A>G p.T371= | Silent (SNP) | VAF 69/134 reads (51%) | called by muse, mutect2, varscan2
- TRPM1 | c.2595C>T p.I865= | Silent (SNP) | VAF 68/390 reads (17%) | called by muse, mutect2, varscan2
- CCHCR1 | c.1799-33T>C | Intron (SNP) | VAF 23/120 reads (19%) | called by muse, mutect2, varscan2
- CILK1 | c.-13G>A | 5'UTR (SNP) | VAF 200/200 reads (100%) | catalogued as rs978937917; called by muse, mutect2, varscan2
- COA5 | c.*52_*55del | 3'UTR (DEL) | VAF 10/122 reads (8%) | called by mutect2, pindel
- DOCK8 | chr9:214703 A>T | 5'Flank (SNP) | VAF 16/452 reads (4%) | called by muse, mutect2
- HCLS1 | c.399+141T>G | Intron (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- LGI1 | c.*25C>G | 3'UTR (SNP) | VAF 28/213 reads (13%) | catalogued as COSV101004482; called by muse, mutect2, varscan2
- LMO7 | c.3562+202C>T | Intron (SNP) | VAF 13/127 reads (10%) | catalogued as rs1038255161; called by muse, mutect2
- OR52A4P | n.987C>G | RNA (SNP) | VAF 29/29 reads (100%) | called by muse, mutect2, varscan2
- RAP2A | c.314+6984G>A | Intron (SNP) | VAF 44/44 reads (100%) | called by muse, mutect2, varscan2
- VPS41 | c.2259+653T>C | Intron (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
